Surgical pathology report (de-identified scan), TCGA case TCGA-49-4512, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4512-01A (Primary Tumor).

FINAL DIAGNOSIS ----- Pathologist:
.. RIGHT MIDDLE LOBE (LOBECTOMY):

SPECIMEN TYPE:
lobectomy.

TUMOR SITE:
right, middle lobe.

HISTOLOGIC TYPE:
adenocarcinoma, Nos.

TUMOR SIZE:
greatest dimension 2.0 cm.

Source: NCI Genomic Data Commons file fb49e71b-c9cc-4c8f-998e-1f24a57b867f (TCGA-49-4512.DDDBAC81-A9E3-42A8-AB35-6D506C58413A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).